Somatic mutation profile of tumor specimen TCGA-BR-8365-01A (aliquot TCGA-BR-8365-01A-21D-2340-08) from TCGA case TCGA-BR-8365, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 70.4 years (25,725 days).
Specimen TCGA-BR-8365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d60a560b-f2e6-45ef-8dda-2c556efd07e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8365-10A (Blood Derived Normal), aliquot TCGA-BR-8365-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80e9a71a-a759-44d8-ba5c-04cf139da90a

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTE1 | c.1502T>G p.I501S | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV53909244; called by muse, mutect2, varscan2
- CADM3 | c.892G>A p.G298S (on ENST00000368125 / NM_001127173.3; = p.G332S on NM_021189.5) | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.153); catalogued as rs1557938790, COSV100930316, COSV63686125; called by muse, mutect2
- CCDC97 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99523693; called by mutect2, varscan2
- CERKL | c.1408A>C p.K470Q (on ENST00000339098 / NM_001030311.2; = p.K444Q on NM_201548.5) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59210134; called by muse, mutect2, varscan2
- CFH | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs201360629, CM124965, COSV66410451; called by muse, mutect2
- CMKLR1 | c.409C>T p.R137C (on ENST00000312143 / NM_001142344.2; = p.R135C on NM_004072.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148287464; called by muse, mutect2, varscan2
- DDX56 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51837113; called by muse, mutect2
- DENND5A | c.1779T>A p.D593E | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.21); catalogued as COSV60235685; called by muse, mutect2
- FBXL13 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as rs149803390; called by muse, mutect2, varscan2
- GALNT13 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745417238, COSV67227982; called by mutect2, varscan2
- GPATCH2L | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55047446; called by muse, mutect2
- GPR87 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as rs561644452, COSV53463019, COSV53463672; called by muse, mutect2, varscan2
- HDAC3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV51837926; called by muse, mutect2, varscan2
- HJURP | c.1478A>G p.K493R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV64979044; called by muse, mutect2, varscan2
- MDM2 | c.853A>C p.T285P | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50700474; called by muse, mutect2, varscan2
- PITPNC1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs777936488, COSV55448359; called by mutect2, varscan2
- SATL1 | c.41C>T p.P14L (on ENST00000395409; = p.P201L on NM_001012980.2) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV60577317; called by muse, mutect2
- TUBB4A | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV51158544; called by muse, mutect2, varscan2
- ARID1A | c.1430dup p.H477Qfs*146 | Frame Shift Ins (INS) | VAF 38/245 reads (16%) | called by mutect2, pindel, varscan2
- MRC1 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- TGFBRAP1 | c.1774A>G p.K592E | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2
- CLK1 | c.747C>T p.Y249= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs1231686057, COSV58434682; called by muse, mutect2, varscan2
- NCALD | c.216C>T p.F72= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs746427178, COSV55273644; called by muse, mutect2
- SLITRK5 | c.1812C>A p.R604= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV61524035; called by muse, mutect2
- XKR6 | c.1398G>A p.P466= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs552864192, COSV58657541; called by mutect2, varscan2
